Somatic mutation profile of tumor specimen TCGA-22-4604-01A (aliquot TCGA-22-4604-01A-01D-1267-08) from TCGA case TCGA-22-4604, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.8 years (26,952 days).
Specimen TCGA-22-4604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffc6df2d-60ec-472d-89d3-f9c1ee45b65d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4604-11A (Solid Tissue Normal), aliquot TCGA-22-4604-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02991c18-4747-4612-a2b8-01dbc0c8d669

The open-access MAF lists 243 somatic variants for this specimen: 193 protein-altering or splice-affecting, 45 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 45, Nonsense Mutation 11, Frame Shift Del 8, Splice Site 4, RNA 4, Splice Region 3, In Frame Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 59/136 reads (43%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.47086C>T p.R15696* (on ENST00000591111; = p.R8272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs1343120755, COSV100624672, COSV59893970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4558C>A p.Q1520K | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52225619; called by muse, mutect2, varscan2
- ABCA10 | c.4557G>T p.E1519D | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV52218836, COSV52225635; called by muse, mutect2, varscan2
- ABRAXAS1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 170/608 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV58948861, COSV58949322; called by muse, mutect2, varscan2
- ACHE | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.733); catalogued as rs779397089, COSV53819184; called by muse, mutect2, varscan2
- ADAMTS14 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as COSV64603811; called by muse, mutect2, varscan2
- ADGRV1 | c.4912C>A p.P1638T | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67979072, COSV67989420; called by muse, mutect2, varscan2
- AGAP3 | c.643G>T p.A215S (on ENST00000622464; = p.A251S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/447 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58995177; called by muse, mutect2, varscan2
- AHDC1 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); catalogued as COSV55940308; called by muse, mutect2, varscan2
- ALDH1L2 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); catalogued as COSV51557442; called by muse, mutect2, varscan2
- ANO7 | c.1627C>T p.R543C (on ENST00000274979; = p.R489C on NM_001370694.2) | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs184837414; called by muse, mutect2, varscan2
- ARHGEF2 | c.1606A>G p.K536E (on ENST00000361247 / NM_001162383.2; = p.K508E on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV58113189; called by muse, mutect2, varscan2
- ATAD2 | c.1525T>A p.S509T | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs907233182, COSV54883288; called by muse, mutect2, varscan2
- ATP10D | c.704A>C p.D235A | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV56709601; called by muse, mutect2, varscan2
- ATP11B | c.2787T>A p.S929R | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100017416, COSV60030406; called by muse, mutect2
- ATP13A4 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55071661; called by muse, mutect2
- ATP8B4 | c.52A>T p.N18Y | Missense Mutation (SNP) | VAF 113/290 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52718943; called by muse, mutect2, varscan2
- BOD1L1 | c.5398G>T p.G1800* | Nonsense Mutation (SNP) | VAF 217/561 reads (39%) | catalogued as COSV50024630; called by muse, mutect2, varscan2
- CA3 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 73/237 reads (31%) | catalogued as rs377151699; called by muse, mutect2, varscan2
- CATSPERB | c.1587G>A p.Q529= | Splice Region (SNP) | VAF 21/120 reads (18%) | catalogued as COSV56429649; called by muse, mutect2, varscan2
- CBLL2 | c.1268G>C p.R423T | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60369541; called by muse, mutect2, varscan2
- CCDC141 | c.2014C>A p.L672I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV55376933; called by muse, mutect2, varscan2
- CCDC39 | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 32/606 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.039); catalogued as COSV56487805, COSV56491340; called by muse, mutect2
- CDH12 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1465712081, COSV66392941, COSV66421592; called by muse, mutect2
- CDH16 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 32/926 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV55337913; called by muse, mutect2
- CGRRF1 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs996372989, COSV53597344; called by muse, mutect2, varscan2
- CHD6 | c.4031A>T p.N1344I | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58559168; called by muse, mutect2, varscan2
- CLOCK | c.2482C>A p.Q828K | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV59403329; called by muse, mutect2
- COPS2 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as rs758202372, COSV54646057; called by muse, mutect2, varscan2
- CPVL | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55304937; called by muse, mutect2, varscan2
- CSMD3 | c.7912C>A p.P2638T (on ENST00000297405 / NM_001363185.1; = p.P2534T on NM_052900.3) | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52169683, COSV52233038, COSV99852242; called by muse, mutect2, varscan2
- CSMD3 | c.3582C>G p.I1194M (on ENST00000297405 / NM_001363185.1; = p.I1090M on NM_052900.3) | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.461); catalogued as COSV52233054; called by muse, mutect2, varscan2
- CTNNA2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs945046536, COSV63582059; called by muse, mutect2, varscan2
- CTNNA3 | c.2653G>T p.V885F | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1241638519, COSV65526274; called by muse, mutect2, varscan2
- CTTN | c.1582G>C p.G528R | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57233824; called by muse, mutect2, varscan2
- DCSTAMP | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV52576279, COSV52578645; called by muse, mutect2
- DEF6 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57354589; called by muse, mutect2, varscan2
- DLGAP2 | c.2266del p.V756Cfs*63 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as COSV101422952, COSV101423006; called by mutect2, pindel, varscan2
- DMPK | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV52179771; called by muse, mutect2, varscan2
- DNAH7 | c.9585G>T p.K3195N | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1024054112, COSV56773123, COSV56784396; called by muse, mutect2, varscan2
- DNM3 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62461748; called by muse, mutect2, varscan2
- DNM3 | c.2441G>A p.R814H (on ENST00000355305 / NM_001350206.2; = p.R808H on NM_015569.5) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as rs763836520, COSV62457160; called by muse, mutect2, varscan2
- DPP9 | c.1423G>T p.G475W (on ENST00000598800; = p.G504W on NM_139159.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV53592506; called by muse, mutect2
- DST | c.9383A>G p.E3128G | Missense Mutation (SNP) | VAF 18/473 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV99754585; called by muse, mutect2
- EBF1 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1185008687, COSV58185419; called by muse, mutect2, varscan2
- EIF4G1 | c.1049C>T p.P350L (on ENST00000346169 / NM_198241.3; = p.P154L on NM_004953.5) | Missense Mutation (SNP) | VAF 96/1226 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV59992157, COSV59993694; called by muse, mutect2
- EIF5B | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as COSV56814522; called by muse, mutect2
- ELP1 | c.2839A>G p.I947V | Missense Mutation (SNP) | VAF 134/229 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV65898553; called by muse, mutect2, varscan2
- ERICH3 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58611453; called by muse, mutect2, varscan2
- F8 | c.4999C>T p.R1667W | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs782562155, CD034859, COSV64275614; called by muse, mutect2, varscan2
- FAM71B | c.399C>G p.H133Q | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100262151, COSV57229775; called by muse, mutect2, varscan2
- FBXW7 | c.1550G>A p.G517E (on ENST00000281708 / NM_001349798.2; = p.G437E on NM_018315.5) | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55931448; called by muse, mutect2, varscan2
- FCSK | c.2290G>T p.V764L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55372742; called by muse, mutect2, varscan2
- FEM1A | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54164314; called by muse, mutect2, varscan2
- FERD3L | c.271del p.R91Afs*7 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as COSV51761969, COSV51764235; called by mutect2, pindel*, varscan2
- FLRT2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58145243; called by muse, mutect2, varscan2
- FUT6 | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs781297476, COSV54605366; called by muse, mutect2
- GABRQ | c.1223T>A p.L408Q | Missense Mutation (SNP) | VAF 79/136 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64782788; called by muse, mutect2, varscan2
- GALNT13 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV67218152, COSV67232119; called by muse, mutect2
- GLUD2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as COSV60152365; called by muse, mutect2
- GMIP | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52557781; called by muse, mutect2, varscan2
- GNA13 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV71474962; called by muse, mutect2
- GPR158 | c.2300G>T p.R767L | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100892876, COSV66274949; called by muse, mutect2, varscan2
- GPR17 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs761150954, COSV55756061; called by muse, mutect2, varscan2
- GRIN2B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV101663184, COSV74205547; called by muse, mutect2, varscan2
- GTF3A | c.997A>G p.R333G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63528653; called by muse, mutect2, varscan2
- HCN1 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.165); catalogued as COSV100297694, COSV100301521, COSV57521384; called by muse, mutect2, varscan2
- HOXB8 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53310963; called by muse, mutect2, varscan2
- HS3ST5 | c.991T>C p.F331L | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.286); catalogued as COSV57145046; called by muse, mutect2, varscan2
- INSR | c.1484-1G>T p.X495_splice | Splice Site (SNP) | VAF 24/97 reads (25%) | catalogued as COSV57166365; called by muse, mutect2, varscan2
- IPO11 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV57578176; called by muse, mutect2, varscan2
- ITPR2 | c.3123-1G>A p.X1041_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as COSV67271929; called by muse, mutect2, varscan2
- KAT5 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 129/491 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV57730039; called by muse, mutect2, varscan2
- KCNJ3 | c.1292del p.G431Efs*5 | Frame Shift Del (DEL) | VAF 52/157 reads (33%) | catalogued as COSV54530895; called by mutect2, pindel, varscan2
- KRT84 | c.952G>C p.V318L | Missense Mutation (SNP) | VAF 236/959 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV57772403; called by muse, varscan2
- LATS1 | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.47); catalogued as COSV53594375, COSV53600121; called by muse, mutect2, varscan2
- LCT | c.4915A>G p.N1639D | Missense Mutation (SNP) | VAF 117/288 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as COSV51552764; called by muse, mutect2, varscan2
- LDHC | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 106/426 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753137116, COSV55004912; called by muse, mutect2, varscan2
- LETM2 | c.749A>T p.D250V (on ENST00000379957 / NM_001286819.2; = p.D155V on NM_144652.3) | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV52686890; called by muse, mutect2, varscan2
- LGSN | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs753482881, COSV65727714; called by muse, mutect2, varscan2
- LRP1B | c.5646G>T p.M1882I | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV67245085; called by muse, mutect2, varscan2
- LRP1B | c.4511G>C p.S1504T | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67190249, COSV67245088; called by muse, mutect2, varscan2
- LRP1B | c.2585G>T p.W862L | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV63341825, COSV63341845; called by muse, mutect2, varscan2
- LRP2 | c.7264A>C p.M2422L | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV55561130; called by muse, mutect2, varscan2
- LRRC4B | c.2093T>C p.L698P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV65350305; called by muse, mutect2, varscan2
- LTB4R2 | c.1111C>T p.R371C (on ENST00000528054; = p.R340C on NM_019839.5) | Missense Mutation (SNP) | VAF 204/368 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs747402319, COSV51866696; called by muse, mutect2, varscan2
- MAGEA6 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 250/456 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV61449178; called by muse, mutect2, varscan2
- MAPK3 | c.941A>T p.N314I | Missense Mutation (SNP) | VAF 122/780 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53774734; called by muse, mutect2, varscan2
- MBTPS1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 25/446 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs377692604; called by muse, mutect2
- MCM4 | c.1792A>T p.I598F | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50626186; called by muse, mutect2, varscan2
- MEP1A | c.1164G>C p.W388C | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57918053, COSV57921239; called by muse, mutect2, varscan2
- MINDY4 | c.1074G>A p.R358= | Splice Region (SNP) | VAF 148/602 reads (25%) | catalogued as COSV54675770; called by muse, mutect2, varscan2
- MOV10L1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 71/247 reads (29%) | catalogued as COSV53174635; called by muse, mutect2, varscan2
- MS4A14 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55730662; called by muse, mutect2, varscan2
- MTHFD2 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV51201787; called by muse, mutect2, varscan2
- MYH15 | c.4724T>A p.L1575H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56313974; called by muse, mutect2, varscan2
- MYO1E | c.592A>G p.R198G | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55690426; called by muse, mutect2, varscan2
- NAV3 | c.6847C>T p.R2283C (on ENST00000397909 / NM_001024383.2; = p.R2261C on NM_014903.6) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749564795, COSV57093034; called by muse, mutect2, varscan2
- NEB | c.7949A>T p.Q2650L | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs753686179, COSV51431984; called by muse, mutect2, varscan2
- NF1 | c.5941A>G p.M1981V (on ENST00000358273 / NM_001042492.3; = p.M1960V on NM_000267.3) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs762935987, COSV62209556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP5 | c.2422C>A p.P808T | Missense Mutation (SNP) | VAF 81/403 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV66765874, COSV66766132; called by muse, mutect2, varscan2
- NPR2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs766118843, COSV61312494, COSV61315234; called by muse, mutect2, varscan2
- NRXN1 | c.3507C>G p.D1169E | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as COSV58467836; called by muse, mutect2, varscan2
- NRXN3 | c.395C>G p.A132G (on ENST00000557594 / NM_001272020.2; = p.A764G on NM_004796.6) | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as COSV55335424, COSV55337534; called by muse, mutect2, varscan2
- OAZ1 | c.49A>T p.R17* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100457284; called by muse, mutect2, varscan2
- OR10S1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 49/184 reads (27%) | catalogued as COSV73342661, COSV73342888; called by muse, mutect2, varscan2
- OR10V1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55699288; called by muse, mutect2, varscan2
- OR10W1 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV67720607, COSV67720767; called by muse, mutect2, varscan2
- OR51F2 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 192/722 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV59065326; called by muse, mutect2, varscan2
- OR5B21 | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1422496073, COSV100835160, COSV64482076; called by muse, mutect2, varscan2
- OR5R1 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs763270212, COSV56572863; called by muse, varscan2
- PALB2 | c.3226C>G p.H1076D | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55167031; called by muse, mutect2, varscan2
- PAPPA2 | c.4085G>A p.R1362H | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768702466, COSV62802802, COSV62813164; called by muse, mutect2, varscan2
- PCDH11X | c.2245G>T p.V749L | Missense Mutation (SNP) | VAF 136/250 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100011064; called by muse, mutect2, varscan2
- PCDH17 | c.782T>A p.V261E | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV64976113; called by muse, mutect2, varscan2
- PCDHGC4 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52757699; called by muse, mutect2, varscan2
- PDIA4 | c.1495C>G p.L499V (on ENST00000286091 / NM_001371244.1; = p.L498V on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 227/903 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV53725514; called by muse, mutect2, varscan2
- PDZD9 | c.545T>C p.I182T (on ENST00000424898 / NM_001363519.1; = p.I122T on NM_173806.4) | Missense Mutation (SNP) | VAF 10/338 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV51672943; called by muse, mutect2
- PEG3 | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 134/511 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV55638949, COSV55651570; called by muse, mutect2, varscan2
- PIK3R2 | c.1712G>T p.R571L | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55848314, COSV55848881; called by muse, mutect2, varscan2
- PITPNM2 | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54903651; called by muse, mutect2, varscan2
- POLR2B | c.2516-1G>A p.X839_splice | Splice Site (SNP) | VAF 47/167 reads (28%) | catalogued as COSV58901435; called by muse, mutect2, varscan2
- PPARD | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.08); catalogued as rs200904269, COSV100283324, COSV61099276; called by muse, mutect2
- PREX2 | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV55782504; called by muse, mutect2, varscan2
- PROX2 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV71520102; called by muse, mutect2, varscan2
- PRPH | c.725G>C p.S242T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV57679064; called by muse, mutect2
- RELL2 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV51837918; called by muse, mutect2, varscan2
- RFX1 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); catalogued as COSV54331204; called by muse, mutect2, varscan2
- RNF31 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 168/304 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0.437); catalogued as COSV99396008; called by mutect2, varscan2
- RPTOR | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 234/677 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs201102317, COSV60806042; called by muse, mutect2, varscan2
- RTP3 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 129/488 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780282555, COSV56124071; called by muse, mutect2, varscan2
- SAYSD1 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 93/680 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV57722943, COSV57723294; called by muse, mutect2, varscan2
- SCML4 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV64636533; called by muse, mutect2, varscan2
- SCN10A | c.4660C>T p.L1554= | Splice Region (SNP) | VAF 82/357 reads (23%) | catalogued as rs745999522, COSV71862046; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINA3 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1406660622, COSV67586568; called by muse, mutect2, varscan2
- SH2D4A | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV56123428; called by muse, mutect2, varscan2
- SHISA3 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 297/712 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59980213; called by muse, varscan2
- SLC29A4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV51875394; called by muse, mutect2, varscan2
- SLC2A5 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs770313806, COSV66237368; called by muse, mutect2, varscan2
- SLC3A2 | c.1838G>C p.R613P | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as COSV58604100; called by muse, mutect2, varscan2
- SLC4A10 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55786821; called by muse, mutect2, varscan2
- SLC6A3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV54366198; called by muse, mutect2, varscan2
- SNRPA | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV54681857; called by muse, mutect2
- SORCS3 | c.3604G>A p.G1202R | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.188); catalogued as COSV63815674; called by muse, mutect2, varscan2
- SORT1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV56667849; called by muse, mutect2
- SPTBN1 | c.2351A>T p.K784M | Missense Mutation (SNP) | VAF 117/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61690447; called by muse, mutect2, varscan2
- ST18 | c.790G>C p.A264P | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52499950, COSV99389969; called by muse, mutect2, varscan2
- STARD8 | c.2842C>A p.Q948K | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as COSV52928786; called by muse, mutect2, varscan2
- TADA3 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.527); catalogued as COSV55028942; called by muse, mutect2, varscan2
- TARS3 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 372/882 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1385410835, COSV60108629; called by muse, mutect2, varscan2
- TBC1D31 | c.2908A>G p.R970G | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV54868020; called by muse, mutect2, varscan2
- TBCD | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350220621, COSV62801310; called by muse, mutect2, varscan2
- TCN1 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 54/532 reads (10%) | catalogued as COSV57253782; called by muse, mutect2
- TECTB | c.951C>G p.H317Q | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV65595808; called by muse, mutect2
- TFPI2 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55991163; called by muse, mutect2, varscan2
- THAP12 | c.1789C>A p.Q597K | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV52611451; called by muse, mutect2, varscan2
- TMIGD2 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 35/982 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs143069562, COSV56667730; called by muse, mutect2
- TNC | c.81A>T p.K27N | Missense Mutation (SNP) | VAF 89/160 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV60786863; called by muse, mutect2, varscan2
- TPCN1 | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 295/1512 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59236915; called by muse, varscan2
- TRADD | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61460674; called by muse, mutect2, varscan2
- TRAM1L1 | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 207/575 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60292541; called by muse, varscan2
- TRAM1L1 | c.1018A>T p.R340* | Nonsense Mutation (SNP) | VAF 233/574 reads (41%) | catalogued as COSV60292549; called by muse, varscan2
- TRIP11 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV50934905; called by muse, mutect2, varscan2
- UBA2 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55829112; called by muse, mutect2, varscan2
- UCP3 | c.431T>G p.F144C | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV58368713; called by muse, mutect2, varscan2
- UHRF1BP1 | c.233A>T p.H78L | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51957629; called by muse, mutect2, varscan2
- ULK4 | c.3633G>T p.E1211D | Missense Mutation (SNP) | VAF 242/443 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV57213963; called by muse, mutect2, varscan2
- UNC13A | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1368546847, COSV53189593; called by muse, mutect2, varscan2
- USF3 | c.6046C>T p.L2016F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377443949; called by muse, varscan2
- WIF1 | c.749G>C p.C250S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54133288; called by muse, mutect2, varscan2
- XKR4 | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59325552; called by muse, mutect2, varscan2
- XRCC5 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV67536902; called by muse, mutect2, varscan2
- ZBTB11 | c.751A>T p.S251C | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV57245821; called by muse, mutect2, varscan2
- ZNF10 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 211/531 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV50213165; called by muse, mutect2, varscan2
- ZNF222 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs573537034, COSV51827375; called by muse, mutect2, varscan2
- ZNF234 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV70603586; called by muse, mutect2
- ZNF423 | c.2042C>T p.S681F (on ENST00000563137 / NM_001379286.1; = p.S673F on NM_015069.4) | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52195965; called by muse, mutect2, varscan2
- ZNF613 | c.860C>G p.S287* (on ENST00000293471 / NM_001031721.4; = p.S251* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 23/203 reads (11%) | catalogued as COSV53272746; called by muse, mutect2, varscan2
- ZNF624 | c.1264G>T p.G422W | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60940651; called by muse, mutect2, varscan2
- ZNF646 | c.4504G>A p.D1502N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54925371; called by muse, mutect2
- ARHGAP1 | c.399_401del p.N133del | In Frame Del (DEL) | VAF 118/420 reads (28%) | called by pindel, varscan2
- ARMH4 | c.2135_2153del p.S712* | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | called by mutect2, pindel, varscan2
- CBLL2 | c.241del p.C81Vfs*21 | Frame Shift Del (DEL) | VAF 70/135 reads (52%) | called by mutect2, pindel*, varscan2
- CBWD5 | c.489T>A p.D163E | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CYP4V2 | c.801+2dup p.X267_splice | Splice Site (INS) | VAF 50/134 reads (37%) | called by mutect2, pindel, varscan2
- DNAH11 | c.7549del p.T2517Qfs*4 | Frame Shift Del (DEL) | VAF 52/196 reads (27%) | called by mutect2, varscan2
- GNPTAB | c.524del p.N175Tfs*38 | Frame Shift Del (DEL) | VAF 23/168 reads (14%) | called by mutect2, pindel, varscan2
- GNPTAB | c.523A>T p.N175Y | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.345); called by mutect2, varscan2
- IGHG1 | c.861C>A p.F287L | Missense Mutation (SNP) | VAF 204/736 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- IGHV3-43 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 111/624 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, varscan2
- POLR1A | c.4081del p.A1361Hfs*7 | Frame Shift Del (DEL) | VAF 55/239 reads (23%) | called by mutect2, pindel, varscan2
- UBN1 | c.3001_3003del p.V1001del | In Frame Del (DEL) | VAF 116/381 reads (30%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13137T>A p.A4379= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV68948566; called by muse, mutect2, varscan2
- ACSS3 | c.1924C>T p.L642= | Silent (SNP) | VAF 64/238 reads (27%) | catalogued as COSV54095175; called by muse, varscan2
- ADAMTS8 | c.624G>A p.T208= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1188838343, COSV57294871; called by muse, mutect2, varscan2
- ADCK1 | c.1455C>T p.S485= | Silent (SNP) | VAF 57/321 reads (18%) | catalogued as rs757640625, COSV53082751; called by muse, mutect2, varscan2
- APOB | c.8859C>T p.P2953= | Silent (SNP) | VAF 71/576 reads (12%) | catalogued as COSV51942327; called by muse, mutect2, varscan2
- APOB | c.7857C>T p.V2619= | Silent (SNP) | VAF 84/351 reads (24%) | catalogued as rs762465145, COSV51942337; called by muse, mutect2, varscan2
- C1QTNF9B | c.399T>C p.T133= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV65944321; called by muse, mutect2, varscan2
- CACNA1D | c.3774A>T p.A1258= (on ENST00000350061 / NM_001128840.3; = p.A1278= on NM_000720.4) | Silent (SNP) | VAF 49/144 reads (34%) | catalogued as COSV55454604; called by muse, mutect2, varscan2
- CACNB4 | c.651G>A p.P217= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs370926360; called by muse, mutect2, varscan2
- CDIN1 | c.222T>C p.N74= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV57712814; called by muse, mutect2
- CTNND2 | c.363C>A p.L121= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as COSV58869707; called by muse, mutect2, varscan2
- EPPK1 | c.1119C>A p.S373= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV73261800; called by muse, mutect2
- FAM135B | c.420G>T p.L140= | Silent (SNP) | VAF 176/599 reads (29%) | catalogued as COSV50526308, COSV50530284; called by muse, mutect2, varscan2
- FOXB2 | c.42G>T p.P14= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100942409, COSV65023597; called by muse, mutect2, varscan2
- GAD2 | c.1452C>T p.I484= | Silent (SNP) | VAF 103/317 reads (32%) | catalogued as COSV52161997; called by muse, mutect2, varscan2
- GFAP | c.1281G>C p.P427= | Silent (SNP) | VAF 91/324 reads (28%) | catalogued as COSV99493235, COSV99493554; called by muse, mutect2, varscan2
- GPR143 | c.351G>T p.V117= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV66632735; called by muse, mutect2, varscan2
- KCNK10 | c.1515G>A p.T505= | Silent (SNP) | VAF 62/393 reads (16%) | catalogued as rs141080520, COSV56647783; called by muse, mutect2, varscan2
- KLRF1 | c.123G>T p.L41= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as COSV54381345; called by muse, mutect2, varscan2
- LAMA5 | c.4503G>A p.P1501= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs200643051; called by muse, mutect2, varscan2
- MS4A14 | c.30A>T p.A10= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV55730224; called by muse, mutect2, varscan2
- NCAPD2 | c.3409C>T p.L1137= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV59700796; called by muse, mutect2, varscan2
- NRG1 | c.936C>T p.Y312= (on ENST00000405005 / NM_013964.5; = p.Y317= on NM_013956.5) | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs79631951, COSV55150262; called by muse, mutect2, varscan2
- OR2B6 | c.936G>A p.K312= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as COSV55129249; called by muse, mutect2, varscan2
- OR5D13 | c.483C>A p.L161= | Silent (SNP) | VAF 103/382 reads (27%) | catalogued as COSV62333434; called by muse, mutect2, varscan2
- PCDHGA5 | c.492G>T p.V164= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV53980297; called by muse, mutect2, varscan2
- PCDHGB3 | c.1545C>T p.F515= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as rs1561553418, COSV53897476; called by muse, mutect2, varscan2
- PLCXD1 | c.948C>G p.L316= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as rs780227650, COSV100397712, COSV58205306; called by muse, mutect2, varscan2
- PRKAR2B | c.564T>G p.G188= | Silent (SNP) | VAF 70/239 reads (29%) | catalogued as COSV55925889; called by muse, mutect2, varscan2
- PSG5 | c.588C>T p.P196= | Silent (SNP) | VAF 255/1022 reads (25%) | catalogued as COSV61654406; called by muse, mutect2, varscan2
- RFX3 | c.228G>T p.T76= | Silent (SNP) | VAF 155/263 reads (59%) | catalogued as COSV56519465, COSV56525627; called by muse, mutect2, varscan2
- RGS6 | c.720C>T p.S240= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV100666432, COSV59585157; called by muse, mutect2
- RIMS1 | c.3711G>A p.S1237= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs761517626, COSV53447344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTRAF | c.717G>A p.L239= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as COSV53499044; called by muse, mutect2, varscan2
- SGIP1 | c.1992C>A p.P664= | Silent (SNP) | VAF 102/227 reads (45%) | catalogued as COSV52773045; called by muse, mutect2, varscan2
- SLC1A7 | c.1281C>A p.L427= | Silent (SNP) | VAF 142/287 reads (49%) | catalogued as COSV57010418, COSV57015034; called by muse, mutect2, varscan2
- SLC25A40 | c.429A>T p.I143= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV100353700, COSV62020751; called by muse, mutect2, varscan2
- SLC28A2 | c.606G>A p.V202= | Silent (SNP) | VAF 100/293 reads (34%) | catalogued as COSV61663467; called by muse, mutect2, varscan2
- SPTA1 | c.984G>A p.E328= | Silent (SNP) | VAF 103/573 reads (18%) | catalogued as COSV63756164; called by muse, mutect2, varscan2
- TBC1D17 | c.741C>T p.S247= | Silent (SNP) | VAF 74/314 reads (24%) | catalogued as rs777178817, COSV55579630; called by muse, mutect2, varscan2
- TBC1D9B | c.2607C>T p.A869= | Silent (SNP) | VAF 89/403 reads (22%) | catalogued as COSV62282758; called by muse, mutect2, varscan2
- TECTA | c.579G>T p.A193= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs759004891, COSV50739768; called by muse, mutect2, varscan2
- TESK1 | c.1431G>A p.P477= | Silent (SNP) | VAF 28/303 reads (9%) | catalogued as rs557615363, COSV52411652; called by muse, mutect2
- WDR43 | c.1338T>C p.D446= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as COSV56099227; called by muse, mutect2
- ZNF668 | c.786G>A p.T262= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs1466498649, COSV56216290; called by muse, mutect2, varscan2
- BAGE2 | n.242G>T | RNA (SNP) | VAF 20/316 reads (6%) | catalogued as rs1302781477; called by muse, mutect2
- HERC2P3 | n.1654G>T | RNA (SNP) | VAF 26/114 reads (23%) | catalogued as rs781414139; called by muse, mutect2, varscan2
- MIR891B | n.12G>T | RNA (SNP) | VAF 62/109 reads (57%) | called by muse, mutect2, varscan2
- NIBAN3 | c.1844-1481G>A | Intron (SNP) | VAF 54/121 reads (45%) | catalogued as rs750069522, COSV99394984; called by muse, mutect2, varscan2
- OFCC1 | n.482A>T | RNA (SNP) | VAF 76/168 reads (45%) | called by muse, mutect2, varscan2
